Surgical pathology report (de-identified scan), TCGA case TCGA-98-8022, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-8022-01A (Primary Tumor).

[page 1 of 3]
Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY

CASE:

Received Date:

Diagnosis

Pleura, right, excision:

- Negative for malignancy.

Lymph node, #4 lymph node, excision:

- Fragments of lymph node negative for malignancy.

Lymph node, #2 lymph node, excision:

- Fragments of lymph node negative for malignancy.

Lymph node, #7 lymph node, excision:

- Fragments of lymph node negative for malignancy.

Lymph node, #8 lymph node, excision:

- Negative for malignancy.

Lymph node, #9 lymph node, excision:

- Fragments of lymph node negative for malignancy.

Lymph node, #10 lymph node, excision:

- Fragments of lymph node negative for malignancy.

Lymph node, #11 lymph node, excision:

- Fragments of lymph node negative for malignancy.

Lung, non anatomic posterior segment right upper lobe, lobectomy:

- Squamous cell carcinoma, moderately to poorly differentiated (0.65cm).
- Tumor is close to the surgical staple line.
- Pathologic stage: pT1AN0MX.

Lung, non anatomic posterior segment right upper lobe, biopsy:

- Squamous cell carcinoma, moderately differentiated.

(Electronically signed by)

Verified:

Clinical Information: The patient is a -year-old male with lung cancer.

Frozen Section Diagnosis

IFS1: Lung, non anatomic posterior segment, right upper lobe, lobectomy:

- No gross nodule identified.
- Pending further sectioning on permanent.
- No frozen section performed.

JFS1: Lung, non anatomic posterior segment, right upper lobe, excision:

- Positive for non small cell carcinoma.

[page 2 of 3]
Gross Description

The specimen is received in ten separate containers, each labeled with the patient's name and medical record number. The first container is further labeled "pleura." It contains a fragment of soft tissue which measures 4 x 2 x 0.5 cm and mostly consists of soft yellow fibroadipose tissue. The specimen is entirely submitted in cassette A1 and A2. The second container is further labeled "#4 lymph node." It contains a fragment of soft tissue which measures 3 x 2.5 x 0.6 cm and contains what appears to be an anthracotic lymph node which measures 0.3 x 0.7 x 0.6 cm and will be entirely submitted in cassette B1. The third container is further labeled "#2 lymph node." It contains a small fragment of tissue which measures 1.5 x 0.5 x 0.4 cm which is bisected and entirely submitted in cassette C1. The fourth container is further labeled "#7 lymph node." It contains three fragments of anthracotic tissue which measures 2 x 1.3 x 0.6 cm and will be entirely submitted in cassette D1. The fifth container is further labeled "#8 lymph node." It contains two fragments of anthracotic soft tissue which measures 1.3 x 0.6 x 0.3 cm in aggregate and will be entirely submitted in cassette E1. The sixth container is further labeled "#9 lymph node." It contains a fragment of anthracotic soft tissue which measures 0.6 x 0.5 x 0.3 cm and will be entirely submitted in cassette F1. The seventh container is further labeled "#10 lymph node." It contains multiple fragments of anthracotic soft tissue which measures 1.5 x 1.5 x 0.5 cm and will be entirely submitted in cassette G1. The eighth container is further labeled "#11 lymph node." It contains a fragment of anthracotic soft tissue which measures 0.6 x 0.5 x 0.5 cm and will be entirely submitted in cassette H1. The ninth container is further labeled "non anatomic posterior segment right upper lobe." It contains a lung lobe which measures 11 x 6 x 3 cm and has been previously serially sectioned in the Frozen Room. The external surface is smooth, pink purplish with moderate amounts of anthracosis. The lung parenchyma is dark-red in color with moderate amounts of anthracosis and no identifiable masses are observed. Representative sections of the lung lobe will be submitted in cassette I1 through I7. The tenth container is further labeled "non anatomic posterior segment right upper lobe." It contains an orange cassette labeled [REDACTED] which contains histowrap with a fragment of soft rubbery tan tissue which measures 0.6 x 0.4 x 0.3 cm and is entirely resubmitted for permanent in cassette J1 [REDACTED]

Block Summary

A1-A2	Pleura.
B1-	#4 Lymph node, entirely submitted.
C1-	#2 Lymph node.
D1-	#7 Lymph node.
E1-	#8 Lymph node.
F1-	#9 Lymph node.
G1-	#10 Lymph node.
H1-	#11 Lymph node.
I1-	Bronchial vascular margin.
I2-	Possible lymph node.
I3-I7	Representative sections of lung tissue.
J1-	Non anatomic posterior segment right upper lobe.

Microscopic Description: A microscopic examination has been performed. [REDACTED]

SP Synoptic Report
I: Thorax Lung

MACRO

SPECIMEN: Lobe(s) of lung: Non-anatomic posterior segment, right upper lobe
PROCEDURE: Segmentectomy
SPECIMEN INTEGRITY: Intact
SPECIMEN LATERALITY: Right
TUMOR SITE: Upper lobe
TUMOR SIZE: Greatest dimension: 0.65 cm
TUMOR FOCALITY: Unifocal

[page 3 of 3]
MICRO

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Tumor extends close to the surgical staple line

BRONCHIAL MARGIN

VASCULAR MARGIN

CHEST WALL MARGIN

OTHER ATTACHED TISSUE MARGIN: Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION: Not identified

LYMPH NODES: Not identified

PRIMARY TUMOR (pT): pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM): Not applicable

Source: NCI Genomic Data Commons file ea8edb5a-6e70-4a97-97ce-378deea45a28 (TCGA-98-8022.A43E983C-2C2A-4D8F-8EB9-4A46F9C4BE43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).